Somatic mutation profile of tumor specimen MP2PRT-PARNFM-TMP1-A (aliquot MP2PRT-PARNFM-TMP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PARNFM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.2 years (1,544 days).
Specimen MP2PRT-PARNFM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a40ffa5d-bf12-4990-979e-fb61c90e0dc8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARNFM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARNFM-NB1-A-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a29f47e7-291a-4498-9687-75d0d6c4c0f2

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATG2A | c.1669C>T p.H557Y | Missense Mutation (SNP) | VAF 328/804 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV65967019; called by muse, mutect2, varscan2
- CALB1 | c.478G>A p.G160R | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99618487; called by muse, mutect2, varscan2
- INHA | c.964C>A p.P322T | Missense Mutation (SNP) | VAF 287/634 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.018); catalogued as COSV54732857; called by muse, mutect2, varscan2
- OR1F1 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 240/586 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as rs546950482, COSV58961193; called by muse, varscan2
- TPP1 | c.1109G>A p.G370E | Missense Mutation (SNP) | VAF 226/573 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs1438779646; called by muse, mutect2, varscan2
- ALPK3 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 294/721 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CALB1 | c.479G>A p.G160E | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1084C>T p.L362= | Splice Region (SNP) | VAF 230/539 reads (43%) | called by muse, mutect2, varscan2
- MMP28 | c.556T>C p.F186L | Missense Mutation (SNP) | VAF 422/923 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- PEAR1 | c.1276G>A p.A426T | Missense Mutation (SNP) | VAF 261/761 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- SERTM2 | c.48T>A p.H16Q | Missense Mutation (SNP) | VAF 197/477 reads (41%) | PolyPhen benign (0.412); called by muse, mutect2, varscan2
- IQGAP2 | c.4410C>T p.P1470= | Silent (SNP) | VAF 244/558 reads (44%) | called by muse, mutect2, varscan2
- PIGR | c.1551C>T p.F517= | Silent (SNP) | VAF 309/676 reads (46%) | catalogued as rs549583756, COSV62904846; called by muse, mutect2, varscan2
- SLC34A2 | c.1569C>A p.A523= | Silent (SNP) | VAF 262/903 reads (29%) | called by muse, mutect2, varscan2
- ABI3BP | c.1577-16676C>T | Intron (SNP) | VAF 194/527 reads (37%) | called by muse, mutect2, varscan2
